Surgical pathology report (de-identified scan), TCGA case TCGA-VR-A8EQ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-A8EQ-01A (Primary Tumor).

ICD O-3
Adenocarcinoma, tubular
821113
Site: Esophagus, distal
third C15.5
JW 1/24/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Esophagus

I-) Product of esophagogastrectomy

- Tubular adenocarcinoma moderately to poorly differentiated affecting the distal esophagus, esophageal-gastric transition and cardia, measuring 7.0 cm in the longest axis.
- The tumor infiltrates the perigastric fat.
- In esophageal tumor infiltrates the adventitia.
- Moderate stromal desmoplasia.
- Mild inflammatory infiltrate in the stroma.
- Presence of foci of lymphatic and perineural tumor infiltration.
- Esophageal circumferential margin compromised by neoplasia.
- Proximal and distal margins uninvolved by neoplasia.
- Gastric and esophageal peri-tumoral mucosa with no peculiarities.
- Absence of neoplasia in two peri-esophageal lymph nodes dissected.
- Tumor implantation in peri - esophageal soft tissue.
- Metastatic adenocarcinoma in 7 of the 13 dissected lymph nodes along the great curvature (7/13).

II-) Esophageal margin

- Absence of neoplasia

allow - per M Aden Base -
SW 6 chori
10/24/13

HPA: Discrepancy		✓

10/24/13
tubular
adenoc

Source: NCI Genomic Data Commons file 0729e46b-9d9d-4b29-8ef8-0169f4018592 (TCGA-VR-A8EQ.7B46A4D8-5E1A-4D92-A657-2F446D7040C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).